Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-6229, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-6229-01A (Primary Tumor).

[page 1 of 4]
Specimen(s) Received

1. Neck: Contents right neck
2. Neck: Deep margin tongue: [REDACTED]
3. Neck: Contents right tongue and floor of mouth, long-posterior, short-anterior, nylon medial
4. Neck: Medial margin right tongue: [REDACTED]
5. Neck: Posterior margin Rt tongue: [REDACTED]
6. Neck: Anterior margin Rt tongue: [REDACTED]
7. Neck: Lateral margin, floor of mouth: [REDACTED]
8. Neck: Rt. neck level 1B

Diagnosis

1. Contents of right neck:
- Submandibular gland with no pathologic changes, negative for malignancy.
- Twenty lymph nodes, negative for malignancy (0/20).
2. Deep margin tongue:
- Negative for malignancy.
3. Right tongue and floor of mouth; resection:
- Squamous cell carcinoma, moderately differentiated.
- a. Maximum tumour diameter is 2.4 cm.
- b. Maximum tumour thickness is 1.5 cm.
- c. Perineural invasion is present.
- d. No lymphovascular invasion is identified.
- e. The tumour is close (0.1 cm) to the medial margin.
- f. The tumour is close (0.4 cm) to the lateral margin.
- g. All other margins are negative for tumour (> 0.5 cm).
4. Medial margin right tongue:
- Negative for malignancy.
5. Posterior margin right tongue:
- Negative for malignancy.

[page 2 of 4]
6. Anterior margin right tongue:
- Negative for malignancy.

7. Lateral margin, floor of mouth:
- Negative for malignancy.

8. Right neck; level IB:
- One lymph node, negative for malignancy (0/1).

Synoptic Data

Specimen Type:	Resection:Tongue and floor of mouth.
Tumor Site:	Tongue
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 2.4 cm Tumor thickness: 1.5 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Present
Additional Pathologic Findings:	Carcinoma in situ
Margins:	Margins uninvolved by tumor Margins uninvolved by tumor - Distance of tumor from closest margin: 0.1 cm Margins: Medial margin.
Pathologic Staging (pTNM):	pT2: Tumor of lip or oral cavity more than 2 cm but not more than 4 cm in greatest dimension pN0: No regional lymph node metastasis for aerodigestive sites Number of regional lymph nodes examined: 21 Number of regional lymph nodes involved: 0 pMX: Distant metastasis cannot be assessed

verified by:

Electronically

Gross Description

1. The specimen labeled with the patient's name and as "Neck: Contents Right Neck" consists of an oriented standard right neck dissection with overall dimensions of 14.0 x 8.0 x 1.7 cm. There is a diagram indicating level I to level IV. The internal jugular vein measures 4.2 cm in length and is otherwise unremarkable. The sternocleidomastoid is unremarkable and measures 4.0 x 3.5 x 0.8 cm. The submandibular gland measures 4.5 x 3.5 x 1.5 cm and is unremarkable. Multiple lymph nodes ranging from 0.2 cm to 1.4 cm are identified in multiple levels. Representative sections are submitted.

1A- submandibular gland

1B- one lymph node bisected level I

1C- multiple lymph nodes level I

[page 3 of 4]
1D- one lymph node bisected level II
1E-soft tissue level II
1F-one lymph node bisected level III
1G-one lymph node bisected level III
1H-multiple lymph nodes level III
1I-multiple lymph nodes level IV

2. The specimen labeled with the patient's name and as "Neck: Deep margin tongue- [REDACTED]" consists of a fragment of tissue that measures 0.7 x 0.7 x 0.3 cm. The specimen is frozen for intraoperative consultation.

2A- frozen section block resubmitted.

3. The specimen is labeled the patient's name and as "Neck: Contents right tongue and floor of mouth, long posterior, short anterior, nylon medial". It consists of a portion of right tongue measuring 2.0 cm SI x 3.5 cm ML x 7.0 cm AP. There are three sutures for orientation. There is an ill-defined tumor involving the dorsal surface of the tongue. The tumor measures 0.8 SI x 1.5 ML x 2.4 AP cm. The tumor is solid in consistency and grey-tan in color. It is located at 0.5 cm from the lateral margin, 0.9 cm from the medial margin, 0.7 cm from the deep margin, 2.2 cm from the anterior margin, and 1.2 from the posterior margin. The remaining tongue mucosa shows white plaques at 0.7 cm from the anterior edge of the tumor. These plaques measure 1.0 cm in aggregate. Representative sections are submitted.

3A- medial margin

3B- lateral margin

3C- anterior margin

3D-posterior margin

3E-3F-tumor with deep margin

3G-tumor with lateral margin

3H-plaques on the anterior tongue

3I-normal tongue.

Two pieces of tumor/one piece normal were taken for tissue bank.

4. The specimen labeled with the patient's name and as "Neck: Medial margin right tongue- [REDACTED]" consists of a fragment of tissue that measures 2.0 x 0.4 x 0.3 cm. The specimen is frozen for intraoperative consultation.

4A- frozen section block resubmitted.

5. The specimen labeled with the patient's name and as "Neck: Right posterior margin right tongue- [REDACTED]" consists of a fragment of tissue that measures 1.0 x 0.7 x 0.1 cm. The specimen is frozen for intraoperative consultation.

5A- frozen section block resubmitted.

6. The specimen labeled with the patient's name and as "Neck: Anterior margin right tongue- [REDACTED]" consists of a fragment of tissue that measures 1.5 x 0.5 x 0.3 cm. The specimen is frozen for intraoperative consultation.

6A- frozen section block resubmitted.

7. The specimen labeled with the patient's name and as "Neck: Lateral margin, floor of mouth- [REDACTED]" consists of a fragment of tissue that measures 0.7 x 0.3 x 0.2 cm. The specimen is frozen for intraoperative consultation.

7A- frozen section block resubmitted.

8. The specimen container is labeled with the patient's name and as "Neck: Right neck level IB". It consists of a fragment of tissue measuring 1.3 x 1.0 x 0.8 cm.

8A- specimen in toto.

[page 4 of 4]
[REDACTED]

Quick Section Diagnosis

- 2. Deep margin, tongue, biopsy: negative for carcinoma.
- 4. Medial margin, right tongue, biopsy: negative for carcinoma.
- 5. Posterior margin, right tongue, biopsy: negative for carcinoma.
- 6. Anterior margin, right tongue, biopsy: negative for carcinoma.
- 7. Lateral margin, floor of mouth, biopsy: negative for carcinoma.

Slides received (multi-parts)

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file dbce9078-a11c-4b2b-b39a-38c276054367 (TCGA-CQ-6229.240009AA-DB8A-4A4A-8829-4DA934E35D15.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).